Somatic mutation profile of cancer-model specimen HCM-CSHL-0177-C25-85A (3D Organoid; aliquot HCM-CSHL-0177-C25-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-CSHL-0177-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.1 years (23,399 days).
Specimen HCM-CSHL-0177-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4c7b22f-fd99-4246-b771-9a9486855e07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0177-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0177-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4535f8c-63e9-4d68-821f-2687a8704259

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 5, Splice Region 2, Frame Shift Ins 2, RNA 1, Splice Site 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | catalogued as rs79850223, CM920180, COSV50107726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 89/230 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 224/230 reads (97%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, varscan2
- ADAMTS10 | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 174/438 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs564996469, COSV54355869; called by muse, mutect2, varscan2
- ADGRB1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 345/768 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs748739348, COSV60096229; called by muse, varscan2
- ATM | c.6680G>A p.R2227H | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs879254132, COSV53768386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.3028C>T p.R1010W | Missense Mutation (SNP) | VAF 95/958 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs757026025; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1E | c.3285A>T p.E1095D | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.186); catalogued as COSV62386722; called by muse, mutect2, varscan2
- CCS | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 371/942 reads (39%) | catalogued as rs767806191; called by muse, mutect2
- CDK19 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100099120; called by muse, mutect2, varscan2
- DCST2 | c.1512C>T p.G504= | Splice Region (SNP) | VAF 36/782 reads (5%) | catalogued as rs896377649; called by muse, mutect2
- GALNT17 | c.871T>A p.S291T | Missense Mutation (SNP) | VAF 49/895 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100354141; called by muse, mutect2
- KIF21B | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 48/612 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.114); catalogued as rs760922988; called by muse, mutect2
- KIF26B | c.4457C>T p.P1486L | Missense Mutation (SNP) | VAF 50/1156 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201038043; called by muse, mutect2
- MUC5B | c.12806C>A p.P4269Q | Missense Mutation (SNP) | VAF 829/848 reads (98%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV71592420; called by muse, mutect2, varscan2
- NMU | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 346/816 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1478413466; called by muse, varscan2
- OR2M5 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 167/292 reads (57%) | catalogued as COSV63546261; called by muse, mutect2, varscan2
- PRL | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 51/895 reads (6%) | catalogued as rs757549608; called by muse, mutect2
- RIPOR3 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 449/844 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs920342685; called by muse, mutect2, varscan2
- ROR2 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 392/622 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs369080860; called by muse, mutect2, varscan2
- TG | c.5188C>T p.R1730C | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs200793895, COSV55070371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1094C>G p.A365G | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ACSM1 | c.1019G>C p.C340S | Missense Mutation (SNP) | VAF 178/281 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AL592490.1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCND2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 408/757 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAJC8 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAF1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- INAVA | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 212/594 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KMT2C | c.12276G>A p.E4092= | Splice Region (SNP) | VAF 67/133 reads (50%) | called by muse, varscan2
- KRTAP3-1 | c.211T>C p.C71R | Missense Mutation (SNP) | VAF 276/792 reads (35%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP85 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 211/353 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10Z1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 157/438 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 324/628 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PLXNA2 | c.1999A>G p.N667D | Missense Mutation (SNP) | VAF 170/421 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PRRC2B | c.5095G>T p.E1699* | Nonsense Mutation (SNP) | VAF 178/463 reads (38%) | called by muse, mutect2, varscan2
- RECK | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- RTL9 | c.2364_2389del p.S789Nfs*72 | Frame Shift Del (DEL) | VAF 117/382 reads (31%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1594_1595insA p.A532Dfs*45 | Frame Shift Ins (INS) | VAF 176/246 reads (72%) | called by mutect2, pindel, varscan2
- SMC1A | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPI1 | c.565dup p.I189Nfs*99 | Frame Shift Ins (INS) | VAF 453/637 reads (71%) | called by mutect2, pindel, varscan2
- TTN | c.59384A>C p.K19795T (on ENST00000591111; = p.K12371T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/272 reads (4%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- UBAC2 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ACSM1 | c.1020C>T p.C340= | Silent (SNP) | VAF 179/280 reads (64%) | called by muse, mutect2, varscan2
- ANKS6 | c.2502C>T p.N834= | Silent (SNP) | VAF 113/162 reads (70%) | catalogued as rs201958764, COSV62051751; called by muse, mutect2, varscan2
- DERL1 | c.531T>C p.N177= | Silent (SNP) | VAF 66/142 reads (46%) | catalogued as rs1166366513; called by muse, mutect2, varscan2
- FAM135B | c.633C>A p.V211= | Silent (SNP) | VAF 102/248 reads (41%) | called by muse, mutect2, varscan2
- OR1A1 | c.114A>T p.T38= | Silent (SNP) | VAF 192/195 reads (98%) | catalogued as COSV100410835; called by muse, mutect2, varscan2
- OR1R1P | c.330C>T p.T110= | Silent (SNP) | VAF 34/640 reads (5%) | called by muse, mutect2
- PPP1R26 | c.2358G>A p.A786= | Silent (SNP) | VAF 93/645 reads (14%) | catalogued as rs764809604; called by muse, mutect2, varscan2
- SEMA5A | c.2220G>A p.P740= | Silent (SNP) | VAF 268/512 reads (52%) | catalogued as rs200621236, COSV66791508; called by muse, mutect2, varscan2
- SLC35E2B | c.1217G>A p.*406= | Silent (SNP) | VAF 53/666 reads (8%) | called by muse, mutect2
- SULF1 | c.1101G>A p.T367= | Silent (SNP) | VAF 42/314 reads (13%) | catalogued as rs146417849; called by muse, varscan2
- THAP4 | c.507A>G p.Q169= | Silent (SNP) | VAF 432/953 reads (45%) | catalogued as rs763282526; called by muse, mutect2, varscan2
- TLE2 | c.2019C>T p.C673= | Silent (SNP) | VAF 164/397 reads (41%) | catalogued as rs1435181899; called by muse, mutect2, varscan2
- TTYH3 | c.522G>A p.L174= | Silent (SNP) | VAF 408/857 reads (48%) | catalogued as COSV99350233; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847139 G>C | 5'Flank (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2, varscan2
- DCHS2 | n.4711T>C | RNA (SNP) | VAF 78/322 reads (24%) | called by muse, mutect2
